Somatic mutation profile of tumor specimen MP2PRT-PAUGJY-TMP1-A (aliquot MP2PRT-PAUGJY-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUGJY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,830 days).
Specimen MP2PRT-PAUGJY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce4f445d-7fc8-4681-a14c-ceb9d2d15d3c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGJY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGJY-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86095a83-3eda-4b33-b6ab-c8721bf8e20a

The open-access MAF lists 36 somatic variants for this specimen: 20 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 13, Intron 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 37/183 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB1 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 136/396 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs1207410576, COSV62347030; called by muse, mutect2, varscan2
- BHMT2 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs776368961; called by muse, mutect2
- CNIH3 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs751126399, COSV55276056; called by muse, mutect2, varscan2
- KDM4D | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782646282; called by muse, mutect2
- KNDC1 | c.2672C>T p.P891L | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs1406658196; called by muse, mutect2, varscan2
- LPA | c.4333C>T p.R1445C | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs778266525, COSV60300378; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 25/89 reads (28%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- LRP1 | c.8179G>A p.E2727K | Missense Mutation (SNP) | VAF 86/259 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1453105883; called by muse, mutect2, varscan2
- TTN | c.56101G>A p.E18701K (on ENST00000591111; = p.E11277K on NM_003319.4) | Missense Mutation (SNP) | VAF 59/311 reads (19%) | PolyPhen probably damaging (0.994); catalogued as rs1015533049; called by muse, mutect2, varscan2
- TXLNB | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 145/455 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs918478354; called by muse, mutect2, varscan2
- ZNF862 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 219/467 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.198); catalogued as rs754322907, COSV99783764; called by muse, mutect2, varscan2
- CLCA4 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGFBP1 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 15/513 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.398); called by muse, mutect2
- MPDU1 | c.50T>A p.L17H | Missense Mutation (SNP) | VAF 198/502 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PASD1 | c.1603C>G p.Q535E | Missense Mutation (SNP) | VAF 74/346 reads (21%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTPRN2 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 36/490 reads (7%) | called by muse, mutect2
- SYNE1 | c.21790G>C p.E7264Q (on ENST00000367255 / NM_182961.4; = p.E7193Q on NM_033071.3) | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP29 | c.1815A>T p.R605S | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- VEGFA | c.287C>T p.P96L (on ENST00000523873 / NM_001171623.1; = p.P276L on NM_003376.6) | Missense Mutation (SNP) | VAF 79/257 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACER1 | c.264C>T p.D88= | Silent (SNP) | VAF 44/484 reads (9%) | catalogued as rs771783022, COSV56834663; called by muse, mutect2
- BCL11B | c.2253C>A p.R751= (on ENST00000357195 / NM_001282237.2; = p.R680= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/704 reads (9%) | called by muse, mutect2
- CBFA2T3 | c.612G>A p.L204= | Silent (SNP) | VAF 11/309 reads (4%) | called by muse, mutect2
- COL24A1 | c.282C>T p.F94= | Silent (SNP) | VAF 138/345 reads (40%) | catalogued as rs533279139, COSV100992790; called by muse, mutect2, varscan2
- DSCAML1 | c.3228C>T p.N1076= (on ENST00000321322; = p.N1016= on NM_020693.4) | Silent (SNP) | VAF 50/280 reads (18%) | catalogued as rs146838018; called by muse, mutect2, varscan2
- GOLGA8S | c.1086G>A p.E362= | Silent (SNP) | VAF 23/471 reads (5%) | catalogued as rs746725456; called by muse, mutect2
- GSG1L | c.291C>G p.L97= | Silent (SNP) | VAF 16/437 reads (4%) | called by muse, mutect2
- IGHV4-28 | c.352_353del p.*118del | Silent (DEL) | VAF 82/146 reads (56%) | called by mutect2, varscan2*
- OBSL1 | c.3915C>T p.D1305= | Silent (SNP) | VAF 24/740 reads (3%) | catalogued as rs926056344; called by muse, mutect2
- PRKD1 | c.2241C>T p.P747= | Silent (SNP) | VAF 119/382 reads (31%) | catalogued as rs147092748; called by muse, mutect2, varscan2
- TGM1 | c.963C>G p.V321= | Silent (SNP) | VAF 20/405 reads (5%) | catalogued as rs760270638; called by muse, mutect2
- TTN | c.55770G>C p.L18590= (on ENST00000591111; = p.L11166= on NM_003319.4) | Silent (SNP) | VAF 69/358 reads (19%) | catalogued as COSV60383370; called by muse, mutect2, varscan2
- TULP4 | c.4416G>A p.P1472= | Silent (SNP) | VAF 167/543 reads (31%) | catalogued as rs369723150; called by muse, mutect2, varscan2
- CYP11B1 | c.239+108G>T | Intron (SNP) | VAF 16/394 reads (4%) | called by muse, mutect2
- TM2D1 | c.439+708G>T | Intron (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- TTN | c.10360+4884T>C | Intron (SNP) | VAF 60/163 reads (37%) | catalogued as rs1351074745, COSV100628816; called by muse, mutect2, varscan2
